Gene-level copy-number profile of tumor specimen ALCH-AE8O-TTP1-A from ALCHEMIST case ALCH-AE8O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.8 years (20,398 days).
Specimen ALCH-AE8O-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cc1e82b9-313c-4613-bdf7-8276557a5900.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE8O-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/d410ed4d-484f-44c4-b0e8-c0d600c15708

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 13,055; copy number 2: 41,867; copy number 3: 3,267; copy number 4: 94; copy number 5: 57; copy number 6: 20; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,301,658–87,302,251, 1 gene: DBF4P3.
- chr8:33,436,268–33,436,700, 1 gene (within-gene range 0–1): AC091144.2.
- chr10:38,423,625–38,423,728, 1 gene: RNU6-1118P.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr22:30,262,829–30,289,622, 3 genes (within-gene range 0–2): OSM, AC004264.2, CASTOR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 79 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,466,699–212,472,905, 1 gene, copy number 5: LINC02771.
- chr1:246,682,108–246,691,821, 2 genes, copy number 7: AL591848.2, AL591848.1.
- chr13:100,062,296–100,063,601, 1 gene, copy number 6: ASNSP3.
- chr14:34,920,858–35,469,330, 21 genes, copy number 5–6: SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, AL133163.3, RPS3AP4.
- chr14:36,061,026–36,656,163, 17 genes, copy number 5 (within-gene range 4–5): AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257.
- chr14:49,598,761–50,335,558, 37 genes, copy number 5 (within-gene range 2–5): LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2.

Autosomal genes at a single copy (total copy number 1): 12,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
